Somatic mutation profile of tumor specimen BA2027D (aliquot aq-BA2027D) from BEATAML1.0 case 2319, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.7 years (25,825 days).
Specimen BA2027D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 078fb674-9664-4e6f-ba2f-5fcc010bedf7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2333D (Solid Tissue Normal), aliquot aq-BA2333D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b5e3c10-0bfe-4c5e-b206-70c16bf5a2bb

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC6A7 | c.1055T>A p.L352Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as COSV100046291; called by muse, mutect2, varscan2
- PEX11B | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- TRABD2A | c.134G>T p.W45L | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RYR3 | c.2991C>T p.D997= | Silent (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
